Surgical pathology report (de-identified scan), TCGA case TCGA-75-5125, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-5125-01A (Primary Tumor).

15-5/25

Sample Collection Details

Histology and staging

Sample Number	Sample Type	Sample Preservation	Site of Tissue	Diagnosis	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (histology)	Tumour Size (cm)	Histology	Grade/ Differentiation	Pathological T	Pathological N	Clinical M	YALCSG Stage	Histology Comments	Show Image
	TUMOUR	FF		Adenocarcinoma						RESECT	RUL	5.30	03	II	T2,N0S	NI	U0		Perivascular soft tissue at vascular resection margin positive.	
	BUFFY	FF		Adenocarcinoma						RESECT	RUL	5.30	03	II	T2,N0S	NI	M0		Perivascular soft tissue at vascular resection margin positive.	

Source: NCI Genomic Data Commons file 56ca4fdb-2e92-4a8e-95a7-8634ab0f6ae8 (TCGA-75-5125.A0AF0DE5-9022-4354-8B9B-FC80E9508889.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).